TCGA case TCGA-BC-A5W4 — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: UNC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6bb5d506-8fca-43f3-90a6-03c915d7ede2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 69 years; Vital status: Dead; Days to death: 547 days (1.5 years).

Diagnoses (3)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 69.8 years (25,503 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T3a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Residual disease: R1; Days to last follow up: 547 days (1.5 years); Child pugh classification: A.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: Yes; Vascular invasion type: Micro.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Synchronous primary of the cecum (histology not recorded by GDC). Age at diagnosis: 69.8 years (25,503 days); AJCC staging edition: 7th; AJCC pathologic T: Tis; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage 0.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 0 days; Treatment anatomic sites: Cecum / Appendix.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS). Age at diagnosis: 70.9 years (25,887 days); Days to diagnosis: 384 days (1.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Ablation or Embolization, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Organ Transplantation to Liver, for recurrent disease; Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Days to follow up: 289 days; Disease response: Tumor Free.
- Day 384 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 384 days (1.1 years).
- Days to follow up: 547 days (1.5 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Platelets 102000 (unit not recorded by GDC) [Blood test normal range lower: 150000; Blood test normal range upper: 440000].
- Albumin 4.2 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].
- Total Bilirubin 0.6 mg/dL [Blood test normal range lower: 0; Blood test normal range upper: 1.2].
- Prothrombin Time 12.9 Seconds [Blood test normal range lower: 9.9; Blood test normal range upper: 13].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 106 kg; Height: 183 cm; BMI: 31.7.
- Timepoint category: Prior to Diagnosis; Risk factors: Alcohol Consumption.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BC-A5W4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 540 mg.
  Slide TCGA-BC-A5W4-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 80; Percent normal cells: 3; Percent necrosis: 0; Percent stromal cells: 7; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-BC-A5W4-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BC-A5W4-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Multiple.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Cecum; Other malignancy histological type: Intramucosal adenocarcinoma.
- Other malignancy form, Surgery: Other malignancy surgery type: Partial cecal resection w/ appy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 547 days; disease-specific survival: no event (censored), 547 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 384 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BC-A5W4-01A-11D-A28W-01): tumor purity 0.93, ploidy 3.64, whole-genome doublings 1.
